Surgical pathology report (de-identified scan), TCGA case TCGA-ZH-A8Y6, project TCGA-CHOL (Cholangiocarcinoma), tissue source site University of North Carolina, specimen TCGA-ZH-A8Y6-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Gallbladder, cholecystectomy

- Benign gallbladder with no significant pathologic abnormality
- One benign lymph node (0/1)
- No carcinoma identified

B: Lymph node, portal, removal

- Six fragments of benign lymph node
- No carcinoma identified

C: Liver, Segments 4-5, partial hepatectomy

Histologic tumor type/subtype: cholangiocarcinoma, mass forming subtype

Histologic grade: grade 2 of 4 (moderately differentiated)

Tumor location: between segments 4 and 5

Tumor size: 3.5 cm

Focality/extent: unifocal

Tumor necrosis/treatment effect: not identified

Vascular invasion: not identified

Perineural invasion: not identified

Capsular invasion: not identified

Margins: uninvolved by tumor; tumor is 0.5 cm from closest margin (segment 4 parenchymal margin)

Lymph nodes: none submitted in this specimen (see specimen B)

Background liver: macrovesicular steatosis involving 65% of hepatic parenchyma with grade 1 steatohepatitis; no evidence of bridging fibrosis or cirrhosis on H & E stain (results of trichrome stain will be issued in an addendum)

AJCC Pathologic TNM Stage: pT1 pN0

NOTE: This pathologic stage assessment is based on information

ICD-O-3

Cholangiocarcinoma 8160/3
Site Intrahepatic bile duct
C22.1

MD 4/3/14

[page 2 of 3]
available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

-year-old female, intrahepatic cholangiocarcinoma.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "gallbladder."

Previously opened or disrupted: no

Measurements: 7.5 x 3.0 x 2.5 cm

External surface: green/gray, smooth and glistening

Luminal contents: green, viscous fluid

Stones present: none

Mucosa: green and velvety

Wall thickness: less than 1 mm

Other comments: cystic duct node is present and measures 0.5 x 0.3 x 0.2 cm, tan/pink

Block #: A1, cystic duct margin, en face, representative section and cystic duct lymph node

Tissue remains in formalin.

Container B is additionally labeled "portal lymph nodes." It holds six fragments measuring 1.3 x 1.5 x 0.3 cm in aggregate of yellow/tan fibrofatty tissue.

Tissue is entirely submitted in blocks B1-B2,

Container C is additionally labeled "Segment 4, 5; short stitch=Segment 6 margin, long stitch=Segment 4 margin. " The specimen contains a 110 gram, 1.5 x 6.9 x 4.3 cm partial hepatectomy. The specimen is received with a short stitch marking the Segment 6 margin which is inked blue, and a long stitch marking the Segment 4 margin which is inked black. The capsule is tan/brown and smooth.

Sectioning reveals a 3.5 x 3.1 x 2.9 cm well circumscribed yellow/tan mass.

Within the center there is a focally hemorrhagic area. The mass is 0.2 mm from the capsule, 0.6 cm from the blue margin, and 0.5 cm from the black margin. No additional masses or lesions are identified. The remaining liver parenchyma is tan/brown and smooth.

Both tumor and normal are submitted to Tissue Procurement.

[page 3 of 3]
Block summary:

C1 - mass with respect to the capsule
C2 - mass with respect to the blue margin
C3 - mass with respect to the black margin
C4-C5 - representative sections of the mass
C6 - normal liver away from mass
Tissue remains in formalin.

Addendum

The purpose of this addendum is to issue results of special stains performed on liver tissue from specimen C that is uninvolved by tumor.

Addendum Comment

DPAS: no evidence of involvement by alpha-1-antitrypsin deficiency
(no DPAS positive globules identified within hepatocytes)
Trichrome: no evidence of increased fibrosis (stage 0)
Reticulin: highlights normal hepatic framework
Iron: no evidence of increased iron deposition

Source: NCI Genomic Data Commons file de722404-0305-452e-a002-e7400d76d9d6 (TCGA-ZH-A8Y6.1308ED5B-3B3F-4E9A-91D6-64507F549473.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).